MP2PRT case MP2PRT-PASFNN — Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia (MP2PRT-ALL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Acute Lymphoblastic Leukemia; Primary site: Hematopoietic and reticuloendothelial systems. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/691897da-be1d-4f7f-9631-f25ad5f67b0d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 3 years; Year of birth: 2005; Vital status: Alive.

Diagnoses (1)
1. Precursor cell lymphoblastic leukemia, not phenotyped: Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 3.3 years (1,193 days); Year of diagnosis: 2008; Days to last follow up: 4,134 days (11.3 years).
   Treatment given: Initial disease status: Initial Diagnosis; Regimen or line of therapy: (PH)  4 weeks Prednisone during Induction, High Dose Methotrexate during Interim Maintenance I; Days to treatment start: 1 day; Days to treatment end: 1,230 days (3.4 years); Number of cycles: 5; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Treatment anatomic sites: Body, total.

Follow-up (1 entry)
- Days to follow up: 4,134 days (11.3 years); Disease response: Complete Response; Progression or recurrence: No; Days progression-free: 4,134 days (11.3 years).

Molecular and laboratory tests
- ABL1 (FISH): Negative.
- BCR (FISH): Negative.
- ETV6 (FISH): Negative.
- KMT2A (FISH): Negative.
- RUNX1 (FISH): Negative.

Other clinical attributes
- Weight: 14.8 kg; Height: 96.4 cm; BMI: 15.926034331; Body surface area: 10.24955648.

Biospecimens (2 samples)
- Sample MP2PRT-PASFNN-NB1-A: Sample type: Blood Derived Cancer - Peripheral Blood, Post-treatment; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
- Sample MP2PRT-PASFNN-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
